Gene-level copy-number profile of tumor specimen TCGA-AR-A2LJ-01A from TCGA case TCGA-AR-A2LJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 40.3 years (14,723 days).
Specimen TCGA-AR-A2LJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.18114439-8780-438d-a7cc-50b73533b619.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A2LJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/930bddfe-bd92-44a4-85f8-8ff31f7c62eb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,302; copy number 4: 53,057; copy number 5: 4; copy number 6: 3,098; copy number 11: 7; copy number 23: 26; copy number 28: 100; copy number 32: 49; copy number 40: 1; copy number 48: 51; copy number 52: 20; copy number 56: 37; copy number 64: 13; copy number 71: 28; copy number 73: 16; copy number 85: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A2LJ-01A-12D-A19X-01): tumor purity 0.4, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 358 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,371,463–71,568,934, 56 genes, copy number 32–64: AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1.
- chr11:71,579,728–71,579,848, 1 gene, copy number 32: KRTAP5-14P.
- chr11:75,260,122–75,351,705, 1 gene, copy number 71 (within-gene range 2–71): ARRB1.
- chr11:75,335,092–78,582,156, 95 genes, copy number 28–85 (broad region; genes not listed).
- chr11:125,625,665–127,408,148, 48 genes, copy number 11–73 (within-gene range 2–73): CHEK1, ACRV1, PATE1, PATE2, PATE3, PATE4, AP000842.3, HYLS1, PUS3, AP000842.2, DDX25, AP000842.1, VSIG10L2, CDON, NAP1L1P1, AP000821.1, AP000821.2, AP001893.3, AP001893.2, RPUSD4, AP001893.1, FAM118B, RNU4-86P, RN7SL351P, SRPRA, FOXRED1, RPL35AP26, TIRAP, AP001318.1, AP001318.2, DCPS, GSEC, ST3GAL4, AP001318.3, KIRREL3, KIRREL3-AS1, AP001783.1, AP002833.1, AP002833.3, KIRREL3-AS2, MIR3167, AP002833.2, KIRREL3-AS3, AP001993.1, AP003121.1, LINC02712, RN7SKP121, RN7SKP279.
- chr17:16,029,157–16,218,185, 1 gene, copy number 48 (within-gene range 2–48): NCOR1.
- chr17:16,084,042–17,591,708, 76 genes, copy number 23–48 (within-gene range 4–48) (broad region; genes not listed).
- chr17:38,671,703–40,136,917, 80 genes, copy number 28 (within-gene range 2–28) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
